Somatic mutation profile of tumor specimen TCGA-66-2755-01A (aliquot TCGA-66-2755-01A-01W-0877-08) from TCGA case TCGA-66-2755, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.9 years (23,348 days).
Specimen TCGA-66-2755-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 159cd18e-ce14-4f75-9d17-753fdc60bbec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2755-11A (Solid Tissue Normal), aliquot TCGA-66-2755-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f709689e-0239-443e-b377-7cff48e4f7d4

The open-access MAF lists 239 somatic variants for this specimen: 188 protein-altering or splice-affecting, 49 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Frame Shift Ins 55, Silent 49, Nonsense Mutation 8, Splice Region 3, Frame Shift Del 2, Splice Site 2, Intron 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 26/191 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as CM162636, COSV55873442, COSV55926654, COSV55949642; called by mutect2, varscan2
- PSPH | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs104894036, CM040258, COSV51910690; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 23/55 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ACACB | c.6418G>T p.A2140S | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV58134557; called by mutect2, varscan2
- ADAM32 | c.1545T>A p.F515L | Missense Mutation (SNP) | VAF 181/574 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV65949274; called by mutect2, varscan2
- AGTPBP1 | c.2872A>G p.M958V (on ENST00000357081 / NM_001330701.2; = p.M918V on NM_015239.2) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1564035628, COSV61271645; called by muse, mutect2, varscan2
- AKAP13 | c.3029A>C p.Q1010P | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV63457012; called by mutect2, varscan2
- ALDH18A1 | c.1585G>C p.V529L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV64662599; called by muse, mutect2
- ALG13 | c.2542A>G p.I848V | Missense Mutation (SNP) | VAF 134/276 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52638916; called by mutect2, varscan2
- ANKRD26 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65794344; called by mutect2, varscan2
- APOB | c.11339C>A p.A3780D | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.196); catalogued as COSV51935225; called by mutect2, varscan2
- ASB5 | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56670672; called by mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 27/170 reads (16%) | catalogued as rs745882580; called by mutect2, varscan2
- C21orf91 | c.887A>T p.N296I (on ENST00000284881 / NM_001100420.2; = p.N295I on NM_017447.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV53032927; called by mutect2, varscan2
- CACNA1I | c.5764C>G p.L1922V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV60808223; called by muse, varscan2
- CCR5 | c.561T>A p.Y187* | Nonsense Mutation (SNP) | VAF 96/296 reads (32%) | catalogued as COSV52751651; called by mutect2, varscan2
- CDKL4 | c.927+7C>A | Splice Region (SNP) | VAF 56/219 reads (26%) | catalogued as COSV66509571; called by muse, mutect2, varscan2
- CEACAM5 | c.1802dup p.D602Rfs*19 | Frame Shift Ins (INS) | VAF 26/204 reads (13%) | catalogued as rs782698410; called by mutect2, varscan2
- CECR2 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52836337; called by muse, mutect2, varscan2
- CHD7 | c.6068G>T p.R2023M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs764358718, COSV71110418; called by muse, mutect2, varscan2
- CHGB | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV66760464; called by muse, mutect2, varscan2
- CHGB | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV66760470; called by muse, mutect2, varscan2
- CHORDC1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV57706022; called by muse, mutect2, varscan2
- CHRM2 | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 187/657 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57772340, COSV57776827; called by mutect2, varscan2
- CHRNA9 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV59574478; called by mutect2, varscan2
- COL5A1 | c.5041G>T p.V1681F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV65664604, COSV65668915; called by mutect2, varscan2
- COL6A5 | c.6479C>T p.S2160L (on ENST00000312481; = p.S2156L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs768029912, COSV55201607; called by muse, varscan2
- COL7A1 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as rs748854484, COSV60395226, COSV60404401; called by muse, varscan2
- CRLF2 | c.597C>G p.Y199* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV101053561; called by muse, mutect2, varscan2
- CTC1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 128/335 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs532695142, COSV59853290; called by mutect2, varscan2
- CTNNA1 | c.1749C>T p.V583= | Splice Region (SNP) | VAF 53/199 reads (27%) | catalogued as rs1203628463, COSV57073864; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTNNA2 | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV63558240; called by mutect2, varscan2
- CTNNA2 | c.2121C>A p.S707R | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs780278071, COSV100562322, COSV58151912; called by mutect2, varscan2
- DAAM2 | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51317694; called by muse, mutect2, varscan2
- DAGLB | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51703938, COSV51706048; called by muse, mutect2, varscan2
- DMD | c.3310A>T p.S1104C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV63754927; called by muse, mutect2, varscan2
- DPP8 | c.1768A>T p.N590Y (on ENST00000341861 / NM_001320875.2; = p.N574Y on NM_017743.6) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55678712; called by muse, mutect2, varscan2
- DTX2 | c.692dup p.H232Tfs*122 | Frame Shift Ins (INS) | VAF 20/164 reads (12%) | catalogued as rs758494603; called by mutect2, pindel
- DYTN | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71752067; called by muse, mutect2
- ELMOD3 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs143405971; called by muse, mutect2
- ENPP3 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV62954221; called by mutect2, varscan2
- EP300 | c.6970dup p.H2324Pfs*55 | Frame Shift Ins (INS) | VAF 13/102 reads (13%) | catalogued as rs754418509; called by mutect2, varscan2
- EPB41 | c.2468C>T p.T823I (on ENST00000343067 / NM_001166005.2; = p.T547I on NM_004437.4) | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766136287, COSV58046603; called by muse, mutect2, varscan2
- ESM1 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 148/580 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.412); catalogued as COSV67318567; called by mutect2, varscan2
- FAM133A | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV59075311; called by muse, mutect2, varscan2
- FAM153B | c.695C>A p.S232Y (on ENST00000253490; = p.S155Y on NM_001265615.1) | Missense Mutation (SNP) | VAF 64/516 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV53686440; called by mutect2, varscan2
- FAM161B | c.1286C>T p.P429L (on ENST00000651776; = p.P366L on NM_152445.3) | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54102181; called by mutect2, varscan2
- FAM47A | c.1457G>T p.R486L | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.909); catalogued as rs1408103342, COSV100649851, COSV60494256; called by muse, varscan2
- FOXA3 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100141144; called by muse, mutect2, varscan2
- FSCB | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 113/407 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV61217989, COSV61219053; called by mutect2, varscan2
- FSHR | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs771137333, COSV58623611; called by mutect2, varscan2
- GBP4 | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV63254289; called by mutect2, varscan2
- GCDH | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.368); catalogued as COSV55820120; called by muse, mutect2, varscan2
- GCNA | c.2024T>G p.V675G | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65461928; called by muse, mutect2
- GET3 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV62002348; called by mutect2, varscan2
- GPR142 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV59519354; called by muse, mutect2, varscan2
- GRAMD1B | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV59204194; called by muse, mutect2, varscan2
- GRB14 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV55738217; called by muse, mutect2, varscan2
- GRID1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV60014973; called by muse, mutect2, varscan2
- GZMK | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV50245108, COSV99140891; called by mutect2, varscan2
- HAO1 | c.402C>A p.Y134* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | catalogued as COSV66492000; called by mutect2, varscan2
- HTR3B | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV52744585, COSV99492050; called by muse, mutect2, varscan2
- IGFN1 | c.3573C>A p.F1191L (on ENST00000295591 / NM_001367841.1; = p.F3648L on NM_001164586.2) | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV55172527; called by muse, mutect2, varscan2
- IL1RAP | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV50761480; called by mutect2, varscan2
- IQCC | c.1167dup p.P390Afs*4 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | catalogued as rs753907631; called by mutect2, varscan2
- IQGAP2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1326314501, COSV57173399; called by muse, mutect2, varscan2
- IQUB | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61239249; called by muse, mutect2, varscan2
- ITPRID1 | c.2915G>A p.C972Y | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60074662; called by muse, mutect2, varscan2
- KDM1B | c.1902G>T p.Q634H (on ENST00000449850; = p.Q401H on NM_153042.4) | Missense Mutation (SNP) | VAF 62/513 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52810733; called by mutect2, varscan2
- KDM5C | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV62891022; called by muse, mutect2, varscan2
- KRTAP21-2 | c.70G>T p.G24* | Nonsense Mutation (SNP) | VAF 68/164 reads (41%) | catalogued as COSV61684156; called by mutect2, varscan2
- LDHB | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV63364722; called by mutect2, varscan2
- LRP2 | c.13936G>A p.A4646T | Missense Mutation (SNP) | VAF 114/526 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs202210831, COSV55553055; called by mutect2, varscan2
- LRP3 | c.1676A>T p.Q559L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53503970; called by muse, mutect2, varscan2
- LRRC30 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV67301723; called by muse, mutect2, varscan2
- LRRC30 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV67301623; called by muse, mutect2, varscan2
- LTBP1 | c.1237T>A p.C413S (on ENST00000404816 / NM_206943.4; = p.C87S on NM_000627.4) | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV63186925; called by muse, mutect2, varscan2
- MAG | c.1617-2A>G p.X539_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV62700561; called by muse, mutect2, varscan2
- MAGEB2 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV66780739; called by muse, mutect2, varscan2
- MAGI2 | c.2887G>C p.A963P | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62659275; called by mutect2, varscan2
- MAP7 | c.1530A>C p.Q510H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV63419650; called by muse, mutect2, varscan2
- MBD6 | c.2085C>T p.P695= | Splice Region (SNP) | VAF 8/44 reads (18%) | catalogued as COSV63074538; called by mutect2, varscan2
- MMRN1 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV53337402; called by muse, mutect2
- MSANTD3-TMEFF1 | c.38dup p.E14Gfs*21 | Frame Shift Ins (INS) | VAF 9/72 reads (13%) | catalogued as rs756460439; called by mutect2, pindel
- MYBPC3 | c.1976T>C p.I659T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs397515941, CM1410886, COSV57027520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1A | c.1682dup p.T562Dfs*32 | Frame Shift Ins (INS) | VAF 8/92 reads (9%) | catalogued as rs746990682; called by pindel, varscan2
- NAV3 | c.109T>G p.C37G | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57079623; called by mutect2, varscan2
- NIPAL4 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 128/497 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57430062; called by mutect2, varscan2
- NR2E1 | c.739+2T>A p.X247_splice | Splice Site (SNP) | VAF 21/100 reads (21%) | catalogued as COSV64561959; called by mutect2, varscan2
- NRP1 | c.609dup p.M204Dfs*16 | Frame Shift Ins (INS) | VAF 5/56 reads (9%) | catalogued as rs752379925; called by pindel, varscan2
- OR11H12 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1376149513, COSV73543692; called by mutect2, varscan2
- OR1J4 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV61589800; called by mutect2, varscan2
- OR4D9 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 168/744 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61434441, COSV61434695; called by mutect2, varscan2
- PAPPA2 | c.68A>T p.N23I | Missense Mutation (SNP) | VAF 215/404 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV62778150, COSV62778844; called by mutect2, varscan2
- PAPPA2 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 112/190 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746443344, COSV62778158; called by mutect2, varscan2
- PLA2G4C | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62785492; called by muse, mutect2, varscan2
- PLCL2 | c.1776G>T p.M592I (on ENST00000615277 / NM_001144382.2; = p.M466I on NM_015184.5) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV67622100; called by muse, mutect2, varscan2
- POPDC3 | c.743A>T p.D248V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54644121; called by muse, mutect2, varscan2
- POTEE | c.2728C>G p.R910G | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV58223549, COSV58230656; called by mutect2, varscan2
- PRAMEF2 | c.83T>A p.M28K | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV53575405, COSV53579976; called by mutect2, varscan2
- PRKDC | c.6061G>T p.G2021C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs541975682, COSV58052261; called by muse, mutect2, varscan2
- PRR23B | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.159); catalogued as rs376706999, COSV61494856; called by mutect2, varscan2
- PSMD9 | c.589dup p.E197Gfs*6 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs765798193; called by pindel, varscan2
- PTGR1 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV53028771; called by mutect2, varscan2
- PTPRZ1 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66436501; called by muse, mutect2, varscan2
- RBPJL | c.272dup p.P92Afs*44 | Frame Shift Ins (INS) | VAF 10/87 reads (11%) | catalogued as rs761146769; called by mutect2, pindel
- RYR2 | c.5149G>T p.A1717S | Missense Mutation (SNP) | VAF 133/253 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as rs547829995, COSV63685492; called by mutect2, varscan2
- RYR3 | c.2752T>A p.Y918N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV66789172; called by muse, mutect2, varscan2
- SACS | c.3518G>C p.W1173S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV66539841; called by muse, mutect2, varscan2
- SCG3 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV55021042, COSV55021257, COSV99591009; called by muse, mutect2, varscan2
- SCN1A | c.5510C>A p.P1837Q (on ENST00000303395 / NM_001202435.3; = p.P1826Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV57669951; called by mutect2, varscan2
- SEC24D | c.2693A>G p.K898R | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs764869843, COSV54879762; called by mutect2, varscan2
- SERPINA7 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 164/336 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV59665794, COSV59667041; called by mutect2, varscan2
- SGMS2 | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.563); catalogued as COSV62989279; called by muse, mutect2, varscan2
- SIRPG | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99403298; called by muse, mutect2
- SLC22A2 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV65266459; called by mutect2, varscan2
- SLC22A9 | c.1408A>G p.M470V | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as rs759896529, COSV54167189; called by mutect2, varscan2
- SLC7A1 | c.1325A>G p.Q442R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.67); catalogued as COSV66330543; called by muse, varscan2
- SLITRK3 | c.2786C>A p.A929D | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53848453; called by mutect2, varscan2
- SPAG17 | c.5449G>A p.A1817T | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60458770; called by mutect2, varscan2
- SPAST | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59514481; called by muse, mutect2, varscan2
- SPEF2 | c.3036G>T p.W1012C | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775017946, COSV61548290; called by mutect2, varscan2
- SPINK5 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs747056451, COSV56253907; called by muse, mutect2, varscan2
- SPINK5 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as COSV56253926; called by mutect2, varscan2
- SPTA1 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV63753008; called by mutect2, varscan2
- STX7 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 107/516 reads (21%) | catalogued as COSV63398729; called by mutect2, varscan2
- SYNE2 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV58360751; called by muse, mutect2, varscan2
- TBC1D10A | c.1252dup p.L418Pfs*87 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | catalogued as rs768534059; called by pindel, varscan2
- TLR3 | c.1864A>G p.I622V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); catalogued as COSV57168572; called by muse, mutect2, varscan2
- TNFRSF13B | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as COSV55427759; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2681T>G p.L894R | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV64101056; called by muse, mutect2, varscan2
- TRAF1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV65868093; called by mutect2, varscan2
- TRH | c.319dup p.A107Gfs*16 | Frame Shift Ins (INS) | VAF 9/58 reads (16%) | catalogued as rs770451471; called by mutect2, varscan2
- TTN | c.32261C>A p.P10754H (on ENST00000591111; = p.P9827H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | PolyPhen benign (0.416); catalogued as COSV60059640; called by muse, varscan2
- VN1R2 | c.881A>C p.Q294P | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59038252; called by muse, mutect2, varscan2
- ZFHX4 | c.4114G>T p.D1372Y | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV50795888, COSV99266657; called by mutect2, varscan2
- ZFHX4 | c.8978A>C p.K2993T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50796083; called by mutect2, varscan2
- ZFP30 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV63622575; called by muse, mutect2, varscan2
- ZNF184 | c.1237A>G p.T413A | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV53004297; called by muse, mutect2, varscan2
- ZNF536 | c.2857G>T p.D953Y | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV62824207; called by mutect2, varscan2
- ZNF804B | c.3775C>A p.H1259N | Missense Mutation (SNP) | VAF 100/388 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV60827890; called by mutect2, varscan2
- ACLY | c.1249dup p.M417Nfs*42 | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- ADCY2 | c.2823dup p.G942Wfs*61 | Frame Shift Ins (INS) | VAF 58/205 reads (28%) | called by mutect2, pindel, varscan2
- ALAD | c.695dup p.L233Pfs*15 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- CATIP | c.254_255insT p.L86Pfs*7 | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | called by mutect2, pindel
- CCDC40 | c.3378dup p.K1127Qfs*59 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- COL26A1 | c.494_495insG p.D165Efs*14 (on ENST00000313669 / NM_001278563.3; = p.D163Efs*14 on NM_133457.4) | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- CTDP1 | c.2256dup p.T753Hfs*66 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- CTNNA1 | c.2326dup p.L776Pfs*102 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | called by mutect2, pindel
- DBR1 | c.248del p.G83Efs*25 | Frame Shift Del (DEL) | VAF 70/434 reads (16%) | called by mutect2, pindel, varscan2
- DDX60L | c.2515_2516insA p.V839Dfs*10 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- DNAH1 | c.10820dup p.H3607Qfs*48 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- DNHD1 | c.13528_13529insG p.L4510Rfs*66 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- FLNC | c.4158dup p.I1387Hfs*18 | Frame Shift Ins (INS) | VAF 7/72 reads (10%) | called by mutect2, pindel
- FRS3 | c.608_609insA p.R204Qfs*11 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- GFUS | c.5dup p.E3* | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, pindel
- GTF2A2 | c.91dup p.Q31Pfs*11 | Frame Shift Ins (INS) | VAF 22/188 reads (12%) | called by mutect2, pindel
- INPPL1 | c.2938dup p.S980Kfs*4 | Frame Shift Ins (INS) | VAF 19/91 reads (21%) | called by mutect2, varscan2
- INPPL1 | c.2939delinsAT p.S980Nfs*4 | Frame Shift Ins (INS) | VAF 11/105 reads (10%) | called by mutect2*, pindel, varscan2*
- KDM3B | c.4854_4855insC p.A1619Rfs*25 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- LMO3 | c.156del p.T53Pfs*16 | Frame Shift Del (DEL) | VAF 54/354 reads (15%) | called by mutect2, pindel, varscan2
- LSP1 | c.735dup p.K246Qfs*26 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- MAGED1 | c.2329dup p.V777Gfs*2 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- MAGEL2 | c.2587dup p.Q863Pfs*45 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel
- MED15 | c.2047dup p.A683Gfs*30 (on ENST00000263205 / NM_001003891.3; = p.A643Gfs*30 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- MEIOC | c.691_692insC p.D231Afs*3 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel*
- MRPS30 | c.552_553insA p.V185Sfs*19 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- NASP | c.624_625insG p.T209Dfs*3 | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- NR1I2 | c.406dup p.Q136Pfs*28 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- OR1L6 | c.760_761insG p.S254Cfs*45 (on ENST00000373684; = p.S218Cfs*45 on NM_001004453.2) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- PAN2 | c.1344dup p.R449Qfs*16 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- POMT2 | c.1744dup p.V582Gfs*3 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | called by mutect2, pindel
- PTPN1 | c.203_204insT p.A69Rfs*2 | Frame Shift Ins (INS) | VAF 8/80 reads (10%) | called by mutect2, pindel
- RIPPLY3 | c.184dup p.A62Gfs*2 | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- RNF123 | c.2197dup p.R733Pfs*7 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | called by mutect2, pindel
- SEPTIN5 | c.674dup p.D226Gfs*4 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- SHANK2 | c.4480dup p.V1494Gfs*6 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- SLC35D3 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- SOX7 | c.1150_1151insC p.S384Tfs*79 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by mutect2, pindel
- SUSD2 | c.528dup p.N177Qfs*104 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- TAS1R1 | c.2232dup p.C745Lfs*6 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- TBC1D9B | c.801dup p.I268Hfs*21 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- TFAP2A | c.820dup p.I274Nfs*11 (on ENST00000482890; = p.I266Nfs*11 on NM_001032280.3) | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- TLL2 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAK1 | c.1036dup p.E346Gfs*34 (on ENST00000327628 / NM_001349247.2; = p.E288Gfs*34 on NM_014965.5) | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel
- UNC13C | c.6022dup p.Q2008Pfs*15 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- WWC1 | c.2431_2432insG p.T811Sfs*35 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- ABCA13 | c.9063T>G p.T3021= | Silent (SNP) | VAF 131/373 reads (35%) | catalogued as COSV71287765; called by mutect2, varscan2
- ABCC12 | c.3015C>G p.G1005= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV60913899; called by muse, mutect2, varscan2
- AHRR | c.741G>T p.L247= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV57086102; called by muse, mutect2, varscan2
- CALCOCO1 | c.177G>T p.R59= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV50414100; called by muse, mutect2, varscan2
- CCNB3 | c.720G>C p.R240= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV52073616; called by muse, mutect2, varscan2
- CDH9 | c.1296T>C p.G432= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as COSV50285601; called by muse, mutect2, varscan2
- CLPTM1L | c.531C>T p.N177= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1186803024, COSV57990496; called by muse, mutect2, varscan2
- COQ10B | c.576A>G p.L192= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV55836343; called by muse, varscan2
- CPED1 | c.2733G>A p.Q911= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV60002253; called by mutect2, varscan2
- DCST1 | c.231A>G p.E77= | Silent (SNP) | VAF 76/133 reads (57%) | catalogued as COSV55051797; called by mutect2, varscan2
- DYSF | c.591C>T p.Y197= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs564416027, CM090599, COSV50328645, COSV50679357; called by muse, mutect2
- F13A1 | c.1452C>T p.F484= | Silent (SNP) | VAF 43/215 reads (20%) | catalogued as COSV53554003; called by mutect2, varscan2
- FAM153B | c.696C>G p.S232= (on ENST00000253490; = p.S155= on NM_001265615.1) | Silent (SNP) | VAF 66/520 reads (13%) | catalogued as COSV53686449; called by mutect2, varscan2
- FEZF1 | c.1011A>T p.I337= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV58658745; called by muse, mutect2, varscan2
- GLI1 | c.2007G>T p.V669= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV57361837; called by muse, varscan2
- GRM8 | c.765T>C p.R255= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV58825809; called by muse, mutect2, varscan2
- HTR3B | c.162C>A p.T54= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as COSV52744598; called by mutect2, varscan2
- IGKV6D-41 | c.6G>T p.V2= | Silent (SNP) | VAF 11/98 reads (11%) | called by mutect2, varscan2
- IGLON5 | c.288C>A p.S96= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV54534531, COSV54535826; called by mutect2, varscan2
- IST1 | c.930A>T p.A310= (on ENST00000535424 / NM_001270976.1; = p.H296L on NM_014761.4) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV58663433; called by mutect2, varscan2
- JAKMIP1 | c.1239A>G p.S413= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV51522086; called by muse, mutect2
- KCNJ5 | c.1014C>T p.T338= | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as COSV57966036; called by mutect2, varscan2
- KCNT1 | c.1135C>A p.R379= (on ENST00000488444; = p.R398= on NM_020822.3) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV53698283, COSV99704674; called by mutect2, varscan2
- LRFN2 | c.702C>A p.P234= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100599013, COSV57825544; called by muse, mutect2, varscan2
- MED24 | c.270G>A p.R90= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV62418622; called by mutect2, varscan2
- MUC16 | c.19791G>T p.V6597= | Silent (SNP) | VAF 139/632 reads (22%) | catalogued as COSV67465630; called by mutect2, varscan2
- MUC3A | c.7518C>T p.T2506= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV60215782; called by muse, mutect2, varscan2
- MYO16 | c.3315G>A p.Q1105= | Silent (SNP) | VAF 9/82 reads (11%) | called by mutect2, varscan2
- OGDHL | c.1746A>T p.V582= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV65102405; called by muse, mutect2, varscan2
- OR10AG1 | c.609G>A p.L203= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV56632903; called by muse, mutect2, varscan2
- OR4C6 | c.255C>G p.S85= | Silent (SNP) | VAF 66/252 reads (26%) | catalogued as rs757786657, COSV58603991; called by mutect2, varscan2
- OR4F6 | c.669G>T p.V223= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as COSV61026773; called by mutect2, varscan2
- OR8B4 | c.417C>A p.V139= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as COSV62069719; called by mutect2, varscan2
- RALBP1 | c.1959G>A p.T653= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs537354453, COSV50035357; called by mutect2, varscan2
- RUFY3 | c.1017G>T p.G339= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV56913578; called by muse, mutect2, varscan2
- SERPINB12 | c.675G>C p.T225= | Silent (SNP) | VAF 84/494 reads (17%) | catalogued as COSV54033165, COSV99501624; called by mutect2, varscan2
- SEZ6L | c.2058C>T p.G686= | Silent (SNP) | VAF 114/572 reads (20%) | catalogued as rs141142000; called by mutect2, varscan2
- SFRP4 | c.696A>G p.R232= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as COSV71412376; called by mutect2, varscan2
- SGPP2 | c.466C>T p.L156= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs772959246, COSV58329036; called by muse, mutect2, varscan2
- SLC11A2 | c.1308A>G p.S436= (on ENST00000394904 / NM_001379455.1; = p.S407= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV50370748; called by mutect2, varscan2
- SLC5A11 | c.864G>A p.T288= | Silent (SNP) | VAF 58/278 reads (21%) | catalogued as rs376534051; called by mutect2, varscan2
- SYT9 | c.672G>A p.L224= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV59618336; called by mutect2, varscan2
- TBC1D32 | c.1926A>G p.A642= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs1326050990, COSV51543304; called by mutect2, varscan2
- TECTB | c.873C>A p.T291= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV101027602; called by muse, mutect2, varscan2
- TMPRSS11F | c.411T>C p.D137= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV62466489; called by muse, mutect2, varscan2
- TNFRSF13B | c.132G>T p.L44= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV55427769; called by muse, mutect2, varscan2
- TTI1 | c.1548G>C p.V516= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs544143684, COSV100989639, COSV65061636; called by muse, mutect2, varscan2
- TTN | c.27870G>A p.V9290= (on ENST00000591111; = p.V8363= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as rs2742338, COSV60059652; called by mutect2, varscan2
- UACA | c.1914A>G p.S638= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs769394198, COSV59855778; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846782 C>A | 5'Flank (SNP) | VAF 20/50 reads (40%) | called by mutect2, varscan2
- TTN | c.10361-4105T>C | Intron (SNP) | VAF 50/394 reads (13%) | catalogued as COSV59918992; called by mutect2, varscan2
